Somatic mutation profile of tumor specimen HCM-WCMC-0747-C50-05A (aliquot HCM-WCMC-0747-C50-05A-02D-A88H-36) from HCMI case HCM-WCMC-0747-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 43.2 years (15,793 days).
Specimen HCM-WCMC-0747-C50-05A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f9b923b-2341-447a-af94-29fbec23d75b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0747-C50-10A (Blood Derived Normal), aliquot HCM-WCMC-0747-C50-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2de1f9ce-6873-4143-94bb-7bd857034fdf

The open-access MAF lists 5,336 somatic variants for this specimen: 4,064 protein-altering or splice-affecting, 1,058 silent, 214 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,469, Silent 1,058, Nonsense Mutation 520, Intron 136, Splice Site 31, Splice Region 29, 3'UTR 28, 5'Flank 15, 3'Flank 14, RNA 13, Frame Shift Ins 11, 5'UTR 8.

Variants (750 of 5,336; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3661C>T p.R1221C | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751215, CM030401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARG1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 177/603 reads (29%) | catalogued as rs104893940, CM920106; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASPM | c.9319C>T p.R3107* | Nonsense Mutation (SNP) | VAF 107/460 reads (23%) | catalogued as rs199422187, CM092387, COSV54123750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 76/453 reads (17%) | catalogued as rs753406334, COSV54125634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.2533G>T p.E845* | Nonsense Mutation (SNP) | VAF 81/271 reads (30%) | catalogued as rs1085307394, CM1313679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1137G>A p.T379= | Splice Region (SNP) | VAF 70/109 reads (64%) | catalogued as rs587783050, CS060517, COSV55733400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.4294C>T p.R1432* | Nonsense Mutation (SNP) | VAF 136/484 reads (28%) | catalogued as rs587779585, CM013250, COSV58591606; ClinVar: pathogenic; called by muse, varscan2
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 103/386 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by muse, mutect2, varscan2
- DYNC2LI1 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 90/383 reads (23%) | catalogued as rs745930390, CM157152, COSV53182974; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 45/190 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1258412021, COSV54063404, COSV54077108; called by muse, mutect2, varscan2
- FLNA | c.3596C>T p.S1199L | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs28935473, CM030673, COSV61040824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSD17B4 | c.698-1G>T p.X233_splice (on ENST00000414835 / NM_001199291.3; = p.X208_splice on NM_000414.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 31/382 reads (8%) | catalogued as rs1554064083, COSV56333420; ClinVar: likely pathogenic; called by muse, mutect2
- LAMA2 | c.4198C>T p.R1400* | Nonsense Mutation (SNP) | VAF 67/177 reads (38%) | catalogued as rs775112258, CM1311877, COSV70350217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MERTK | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878853354, CM148731, COSV54927455; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 121/462 reads (26%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2, varscan2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 77/284 reads (27%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 104/395 reads (26%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.3316C>T p.R1106* | Nonsense Mutation (SNP) | VAF 117/414 reads (28%) | catalogued as rs202033121, CM094636; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 167/555 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 182/599 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 121/366 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PSMD12 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 81/315 reads (26%) | catalogued as rs1114167442, COSV62065273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4934G>A p.R1645Q (on ENST00000303395 / NM_001202435.3; = p.R1634Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121917976, CM072001, CM1511233, COSV57662283; ClinVar: pathogenic; called by muse, varscan2
- SPTA1 | c.4975C>T p.R1659* | Nonsense Mutation (SNP) | VAF 48/258 reads (19%) | catalogued as rs1394141324, CM085728, COSV100935534; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 110/408 reads (27%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMEM126A | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 231/720 reads (32%) | catalogued as rs121434508, CM092006, COSV58735100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 95/318 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs886039513, CM145649, COSV55497204; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WAC | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 90/378 reads (24%) | catalogued as rs886041614, COSV61567179; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.4411C>A p.L1471I | Missense Mutation (SNP) | VAF 39/603 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100588709; called by muse, mutect2
- A2ML1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 134/409 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV55285440; called by muse, mutect2, varscan2
- AADAC | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 122/410 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99233421; called by muse, mutect2, varscan2
- ABCA10 | c.1582T>G p.L528V | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52228238; called by muse, mutect2, varscan2
- ABCA3 | c.1554C>A p.Y518* | Nonsense Mutation (SNP) | VAF 79/308 reads (26%) | catalogued as COSV57052448; called by muse, mutect2, varscan2
- ABCA8 | c.3440C>A p.S1147Y | Missense Mutation (SNP) | VAF 93/332 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.396); catalogued as COSV104393298; called by muse, mutect2, varscan2
- ABCB6 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 116/397 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as rs147046586; called by muse, mutect2, varscan2
- ABCC11 | c.3904G>A p.D1302N | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174748693, COSV62321883; called by muse, mutect2
- ABCC8 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 126/346 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV56848000; called by muse, mutect2, varscan2
- ABCE1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 77/394 reads (20%) | catalogued as COSV56846807; called by muse, mutect2, varscan2
- ABCG2 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 61/291 reads (21%) | catalogued as rs201034377, COSV52948355; called by muse, mutect2, varscan2
- ABHD12B | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 136/451 reads (30%) | catalogued as rs909563542; called by muse, mutect2, varscan2
- ABHD16B | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53863610; called by muse, mutect2, varscan2
- ABHD5 | c.819G>T p.K273N (on ENST00000458276 / NM_001365650.1; = p.E336* on NM_016006.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/413 reads (31%) | catalogued as rs762662276, CM122662; called by muse, mutect2, varscan2
- AC069544.2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV65683908; called by muse, mutect2, varscan2
- AC098582.1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 105/317 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs771388611; called by muse, mutect2, varscan2
- AC099489.1 | c.4237G>A p.A1413T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs777140143; called by muse, mutect2, varscan2
- AC231657.3 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs782678518; called by muse, mutect2, varscan2
- ACACA | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 65/675 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416116296; called by muse, mutect2
- ACADM | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 123/441 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769906625, COSV63720304; called by muse, mutect2, varscan2
- ACAP2 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 122/438 reads (28%) | catalogued as rs897760774; called by muse, mutect2, varscan2
- ACAP3 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV61223726; called by muse, mutect2, varscan2
- ACBD4 | c.659G>A p.R220H (on ENST00000376955 / NM_001378111.1; = p.P223= on NM_024722.4) | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs557303418; called by muse, mutect2, varscan2
- ACO1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199823143, COSV59378955; called by muse, mutect2, varscan2
- ACRBP | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 56/284 reads (20%) | catalogued as COSV57523840, COSV57524678; called by muse, mutect2, varscan2
- ACSM2B | c.1449G>T p.M483I | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100312656; called by muse, mutect2, varscan2
- ACSM5 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 105/350 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs369151501; called by muse, mutect2, varscan2
- ACSS1 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 127/354 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs752186614; called by muse, mutect2, varscan2
- ACTC1 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as COSV51760211; called by muse, mutect2, varscan2
- ACTN2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV104426763, COSV63978633; called by muse, varscan2
- ACTN2 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1270659015; called by muse, mutect2, varscan2
- ACTN3 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232811519, COSV72207678; called by muse, mutect2, varscan2
- ACTR1A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV64024400; called by muse, varscan2
- ACTR5 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs768469393; called by muse, mutect2, varscan2
- ACVR1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 118/420 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55116621; called by muse, mutect2, varscan2
- ADAL | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 96/339 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1344077571; called by muse, mutect2, varscan2
- ADAM15 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as rs754878868, COSV99665288; called by muse, mutect2, varscan2
- ADAM18 | c.1068T>G p.I356M | Missense Mutation (SNP) | VAF 103/348 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs201596679; called by muse, mutect2, varscan2
- ADAMTS1 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 40/411 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373807387; called by muse, varscan2
- ADAMTS12 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 176/512 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as rs146144250; called by muse, mutect2, varscan2
- ADAMTS18 | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 104/189 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as rs144292157; called by muse, mutect2, varscan2
- ADAMTS18 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 89/166 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs775057284, COSV51408503; called by muse, mutect2, varscan2
- ADAMTS20 | c.2335C>A p.L779I | Missense Mutation (SNP) | VAF 87/266 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV101166252; called by muse, mutect2, varscan2
- ADAMTS9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 98/368 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759664813, COSV55774765; called by muse, mutect2, varscan2
- ADAR | c.3477G>T p.K1159N | Missense Mutation (SNP) | VAF 40/553 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1268794909, COSV52714157; called by muse, mutect2
- ADCK1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 113/363 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs748957337, COSV99452248; called by muse, mutect2, varscan2
- ADD3 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs767558945, COSV53321083; called by muse, mutect2, varscan2
- ADGRB3 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs779693752; called by muse, mutect2, varscan2
- ADGRF1 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV64800624; called by muse, mutect2, varscan2
- ADGRF5 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 78/298 reads (26%) | catalogued as COSV51937265; called by muse, mutect2, varscan2
- ADGRG4 | c.5974C>A p.L1992I | Missense Mutation (SNP) | VAF 133/450 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV54950689; called by muse, mutect2, varscan2
- ADGRG7 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 144/520 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751437270, COSV56301212, COSV99840688; called by muse, mutect2, varscan2
- ADGRL2 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 33/499 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54653592; called by muse, mutect2
- ADGRL2 | c.2518G>T p.D840Y (on ENST00000370717 / NM_001366005.1; = p.D827Y on NM_012302.4) | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1189334334, COSV54677538; called by muse, mutect2, varscan2
- ADGRL3 | c.3002G>A p.R1001Q (on ENST00000506720 / NM_001322402.2; = p.R933Q on NM_015236.6) | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.888); catalogued as rs370040630; called by muse, mutect2
- ADGRL4 | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs547554975, COSV66064053; called by muse, mutect2, varscan2
- ADGRV1 | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 97/402 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs755180090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.7771G>A p.E2591K | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs757315634, COSV67978987; called by muse, mutect2, varscan2
- ADGRV1 | c.15106G>A p.D5036N | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867504287, COSV67991999; called by muse, mutect2
- ADH6 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52955267; called by muse, mutect2, varscan2
- ADIPOR2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 164/455 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as rs200483941, COSV63946468; called by muse, mutect2, varscan2
- ADNP2 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 115/356 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs377757808; called by muse, mutect2, varscan2
- ADRA1D | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs1405319810; called by muse, mutect2, varscan2
- ADRB2 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 141/450 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60005280; called by muse, mutect2, varscan2
- AFF2 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 84/354 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60664320; called by mutect2, varscan2
- AFG3L2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs765665699; called by muse, mutect2, varscan2
- AGAP2 | c.2189G>A p.R730Q (on ENST00000547588 / NM_001122772.2; = p.R394Q on NM_014770.4) | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs867161743, COSV57731334; called by muse, mutect2, varscan2
- AGBL5 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 106/356 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100549432; called by muse, mutect2, varscan2
- AGL | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 181/678 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as rs776599112, CM140956, COSV54048187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGMAT | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 118/408 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs768542408, COSV65435781; called by muse, mutect2
- AGMO | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs1273447604, COSV61105744; called by muse, mutect2, varscan2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 163/280 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AGPS | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51560637, COSV51563645; called by muse, mutect2, varscan2
- AGRN | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as rs143976046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK | c.6985G>T p.D2329Y | Missense Mutation (SNP) | VAF 164/547 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99945396; called by muse, mutect2, varscan2
- AHNAK | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs745885352, COSV99947730; called by muse, mutect2, varscan2
- AHRR | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100327991; called by muse, mutect2, varscan2
- AJUBA | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1397058735; called by muse, mutect2
- AKAP13 | c.4088C>T p.S1363L | Missense Mutation (SNP) | VAF 97/384 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs911991539; called by muse, mutect2, varscan2
- AKR1B15 | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV71152860; called by mutect2, varscan2
- AKR1E2 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs768333050, COSV53630547; called by muse, mutect2, varscan2
- AKT3 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 38/776 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV55609365; called by muse, mutect2
- AL035461.3 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 139/457 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.515); catalogued as rs778702816; called by muse, mutect2, varscan2
- AL592490.1 | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 121/376 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69425764; called by muse, mutect2, varscan2
- AL592490.1 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 105/436 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs866867581, COSV69424742, COSV69427786; called by muse, mutect2
- ALDH1B1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs770780314, COSV66620189; called by muse, varscan2
- ALMS1 | c.5301T>G p.I1767M | Missense Mutation (SNP) | VAF 34/427 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs146648835; called by muse, mutect2
- ALMS1 | c.11746G>A p.E3916K | Missense Mutation (SNP) | VAF 98/620 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs547320841, COSV52507289; called by muse, mutect2, varscan2
- ALYREF | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as rs1567861648; called by muse, mutect2, varscan2
- AMDHD1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201031842; called by muse, mutect2, varscan2
- AMER1 | c.2642G>A p.R881Q | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs372769953, COSV57668176, COSV57671832; called by muse, mutect2, varscan2
- AMER1 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs200339567; called by muse, varscan2
- AMFR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 206/422 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV51920352; called by muse, mutect2, varscan2
- AMIGO3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV57537835; called by muse, mutect2, varscan2
- AMN1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 50/424 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55670827; called by muse, mutect2, varscan2
- AMN1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 89/354 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as rs765159439, COSV55670682; called by muse, mutect2, varscan2
- ANAPC4 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59543328; called by muse, mutect2
- ANGPT2 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100290422; called by muse, varscan2
- ANGPTL3 | c.1043C>A p.S348Y | Missense Mutation (SNP) | VAF 44/566 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.185); catalogued as COSV52011023; called by muse, mutect2
- ANGPTL7 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.068); catalogued as COSV63872036; called by mutect2, varscan2
- ANK2 | c.10925G>A p.R3642Q | Missense Mutation (SNP) | VAF 202/341 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757939990, COSV52166643; called by muse, mutect2, varscan2
- ANKAR | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 112/392 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55617775; called by muse, mutect2, varscan2
- ANKFN1 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 101/284 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs761277860, COSV59456319; called by muse, mutect2, varscan2
- ANKRD26 | c.3058C>T p.R1020C | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as rs761804757; called by muse, mutect2, varscan2
- ANKRD28 | c.2143C>T p.R715W | Missense Mutation (SNP) | VAF 80/452 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs202220330; called by muse, mutect2, varscan2
- ANKRD30BL | c.539G>T p.R180M | Missense Mutation (SNP) | VAF 52/566 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV54613561; called by muse, mutect2
- ANKRD36 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.846); catalogued as rs946488323, COSV70736234; called by muse, mutect2, varscan2
- ANKRD36B | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 50/590 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs750175150; called by muse, mutect2
- ANKRD62 | c.608T>G p.F203C | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.369); catalogued as COSV58409849; called by muse, mutect2, varscan2
- ANKS6 | c.1994T>C p.L665S | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1249605155; called by muse, mutect2, varscan2
- ANO8 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV50174155; called by muse, mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 169/390 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2, varscan2
- ANP32E | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs782603651, COSV58481542; called by muse, mutect2, varscan2
- ANTXR1 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs747143387, COSV58023545; called by muse, varscan2
- ANXA13 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 111/428 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as rs201212750, COSV51623085, COSV51626415; called by muse, mutect2, varscan2
- ANXA8 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1234169612; called by muse, mutect2
- AOAH | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773369283, COSV99333792; called by mutect2, varscan2
- AOC2 | c.2118C>A p.F706L (on ENST00000253799 / NM_009590.4; = p.F679L on NM_001158.5) | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs772005140, COSV53824129, COSV53826096; called by muse, mutect2, varscan2
- AP000721.1 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 50/142 reads (35%) | PolyPhen probably damaging (0.937); catalogued as COSV100034331; called by mutect2, varscan2
- AP1AR | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 153/549 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs367798505; called by muse, mutect2, varscan2
- AP2A1 | c.2592C>A p.F864L | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV58242275; called by muse, mutect2, varscan2
- APBA1 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595980, COSV99597291; called by mutect2, varscan2
- APOB | c.9849C>A p.F3283L | Missense Mutation (SNP) | VAF 110/309 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51936132; called by muse, mutect2, varscan2
- APOB | c.1931C>A p.S644Y | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs147173587, COSV51922803, COSV51933707; called by muse, mutect2, varscan2
- APOBEC3B | c.225C>A p.F75L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as rs1025766300; called by mutect2, varscan2
- APOBEC3F | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 64/160 reads (40%) | catalogued as rs773563808, COSV100415089; called by muse, mutect2, varscan2
- APOD | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 129/413 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs150503831; called by muse, mutect2, varscan2
- APOL5 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs887484530; called by muse, mutect2, varscan2
- ARAP2 | c.4871G>A p.R1624Q | Missense Mutation (SNP) | VAF 115/398 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1249697981, COSV58292022; called by muse, mutect2, varscan2
- AREG | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 161/538 reads (30%) | catalogued as rs1283640826; called by muse, mutect2, varscan2
- ARHGAP11A | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 114/494 reads (23%) | catalogued as rs1487117985, COSV64381180; called by muse, varscan2
- ARHGAP21 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57605752; called by muse, mutect2
- ARHGAP26 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 158/585 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1191015382, COSV50835979; called by muse, mutect2, varscan2
- ARHGAP29 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 117/430 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53110295, COSV99558207; called by muse, mutect2, varscan2
- ARHGAP30 | c.2401G>T p.G801* | Nonsense Mutation (SNP) | VAF 32/528 reads (6%) | catalogued as COSV63518285; called by muse, mutect2
- ARHGAP36 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs866578619, COSV99357958; called by muse, mutect2, varscan2
- ARHGAP4 | c.1530G>T p.E510D | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV63133250, COSV63134924; called by muse, varscan2
- ARHGDIB | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as rs774401441, COSV56763076; called by muse, mutect2, varscan2
- ARHGEF10 | c.2012A>G p.D671G (on ENST00000398564; = p.D646G on NM_014629.4) | Missense Mutation (SNP) | VAF 142/483 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446957268; called by muse, mutect2, varscan2
- ARHGEF17 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1226836790; called by muse, mutect2, varscan2
- ARHGEF17 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1285187269; called by muse, mutect2, varscan2
- ARHGEF25 | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99677913; called by muse, mutect2, varscan2
- ARHGEF3 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 134/435 reads (31%) | catalogued as COSV99575465; called by muse, mutect2, varscan2
- ARL14 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 178/526 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV57899577; called by muse, varscan2
- ARMC2 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 90/346 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs377734728; called by muse, mutect2, varscan2
- ARMC9 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 125/315 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV63020947; called by muse, mutect2, varscan2
- ARPC1A | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 116/417 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1159010389, COSV99501160; called by muse, mutect2, varscan2
- ARRB2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs771693958, COSV99036395; called by muse, mutect2, varscan2
- ARRDC3 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 118/486 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779678796; called by muse, varscan2
- ARSK | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.324); catalogued as COSV66170448; called by muse, mutect2, varscan2
- ASAH1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 90/311 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); catalogued as COSV50501972, COSV50504395; called by muse, mutect2, varscan2
- ASAP1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 181/606 reads (30%) | catalogued as COSV100727209; called by muse, mutect2, varscan2
- ASB12 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.001); catalogued as rs745631393, COSV100744608, COSV100744742; called by muse, mutect2, varscan2
- ASB14 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 185/607 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs758842851, COSV55700742; called by muse, mutect2, varscan2
- ASB15 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 131/375 reads (35%) | catalogued as COSV99306792; called by muse, mutect2, varscan2
- ASH1L | c.4024C>T p.R1342* | Nonsense Mutation (SNP) | VAF 96/397 reads (24%) | catalogued as COSV64213851; called by muse, mutect2, varscan2
- ASMTL | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 101/371 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779211999, COSV101187833; called by muse, varscan2
- ASNS | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV51552598; called by muse, mutect2, varscan2
- ASPM | c.10269G>T p.K3423N | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV104399271; called by mutect2, varscan2
- ASTN2 | c.2183C>T p.S728L (on ENST00000313400 / NM_001365069.1; = p.S677L on NM_014010.5) | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144736118; called by muse, mutect2, varscan2
- ASXL2 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 30/251 reads (12%) | catalogued as COSV55456602; called by muse, mutect2, varscan2
- ASXL2 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 54/252 reads (21%) | catalogued as COSV55454380; called by muse, mutect2, varscan2
- ASXL3 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV99323704; called by muse, mutect2, varscan2
- ATAD2 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV99783984; called by muse, mutect2, varscan2
- ATE1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 97/355 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs773450449, COSV56435136; called by muse, mutect2, varscan2
- ATF6B | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 119/334 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.644); catalogued as rs199610969; called by muse, mutect2, varscan2
- ATG12 | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 131/431 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.721); catalogued as rs561465491; called by muse, mutect2, varscan2
- ATG2B | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 125/373 reads (34%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.963); catalogued as rs772425977, COSV55890367; called by muse, mutect2, varscan2
- ATP10D | c.2791G>T p.A931S | Missense Mutation (SNP) | VAF 141/477 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56706580; called by muse, mutect2, varscan2
- ATP1A1 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 141/497 reads (28%) | catalogued as rs759845712; called by muse, mutect2, varscan2
- ATP1A1 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 18/346 reads (5%) | catalogued as COSV55192887; called by muse, mutect2
- ATP2A2 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 94/412 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs757914881, CM113597; called by muse, mutect2, varscan2
- ATP2B3 | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs781787078, COSV54850391; called by muse, mutect2, varscan2
- ATP2B3 | c.3115C>T p.L1039F | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.204); catalogued as rs782241469; called by muse, mutect2, varscan2
- ATP5PB | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 148/526 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751833359, COSV52384704; called by muse, mutect2, varscan2
- ATP6AP2 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV101011496, COSV65797177; called by muse, mutect2, varscan2
- ATP6V1H | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 51/630 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.072); catalogued as rs1276055868, COSV62218206; called by muse, mutect2
- ATP7B | c.1870G>T p.E624* | Nonsense Mutation (SNP) | VAF 97/284 reads (34%) | catalogued as COSV54445782; called by muse, mutect2, varscan2
- ATP8A1 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 72/399 reads (18%) | catalogued as rs755553887, COSV100046625; called by muse, mutect2, varscan2
- ATP8A2 | c.3549G>T p.K1183N | Missense Mutation (SNP) | VAF 145/455 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV54939053; called by muse, mutect2, varscan2
- ATP8B1 | c.3041G>A p.R1014Q | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.211); catalogued as rs756828618; called by muse, varscan2
- ATP8B3 | c.3488G>A p.S1163N | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs750848646; called by muse, mutect2, varscan2
- ATP8B4 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 64/170 reads (38%) | catalogued as rs940798819, COSV52710402; called by muse, mutect2, varscan2
- ATP8B4 | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV52726883; called by mutect2, varscan2
- ATR | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 74/296 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV63384749; called by muse, varscan2
- ATRX | c.5386G>T p.D1796Y | Missense Mutation (SNP) | VAF 143/541 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970229; called by muse, mutect2, varscan2
- ATXN2 | c.3632C>T p.T1211M (on ENST00000550104; = p.T1051M on NM_002973.4) | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1198968756, COSV57981626; called by muse, mutect2, varscan2
- AXDND1 | c.736A>G p.T246A | Missense Mutation (SNP) | VAF 58/324 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs754536225; called by muse, mutect2, varscan2
- B2M | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs986783978; called by muse, mutect2, varscan2
- B4GALNT2 | c.200G>T p.R67I | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs777942057; called by muse, mutect2, varscan2
- BACH1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 114/476 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750785692, COSV54518596; called by muse, mutect2, varscan2
- BANK1 | c.2005C>T p.L669F | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV59840312; called by muse, mutect2, varscan2
- BARD1 | c.2221G>T p.D741Y | Missense Mutation (SNP) | VAF 89/403 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs587780029, COSV53616112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1A | c.4508C>T p.S1503L | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1389574742, COSV62409622; called by muse, mutect2, varscan2
- BAZ2B | c.6416T>G p.F2139C | Missense Mutation (SNP) | VAF 154/515 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58603397; called by muse, mutect2, varscan2
- BCAS3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 116/407 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs773183785, COSV101175451; called by muse, mutect2, varscan2
- BCCIP | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 239/791 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751497919, COSV104372773; called by muse, mutect2, varscan2
- BCL6B | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs751964952, COSV99546933; called by muse, mutect2, varscan2
- BCL7C | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1319181407; called by muse, mutect2, varscan2
- BDP1 | c.5644G>T p.E1882* | Nonsense Mutation (SNP) | VAF 41/687 reads (6%) | catalogued as rs1561748460; called by muse, mutect2
- BEND2 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 42/479 reads (9%) | catalogued as rs1400847250; called by muse, mutect2
- BEND4 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 94/319 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV72468902; called by muse, mutect2, varscan2
- BEX1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 66/261 reads (25%) | catalogued as COSV101022493; called by muse, varscan2
- BEX1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as COSV65579974; called by muse, varscan2
- BIRC6 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 103/344 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196110; called by muse, mutect2, varscan2
- BLMH | c.1190C>A p.S397* | Nonsense Mutation (SNP) | VAF 131/376 reads (35%) | catalogued as COSV55585076; called by muse, mutect2, varscan2
- BLZF1 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 109/447 reads (24%) | catalogued as COSV99051517; called by muse, mutect2, varscan2
- BMP2 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV66578028; called by muse, mutect2, varscan2
- BMP7 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV67780098; called by muse, mutect2, varscan2
- BMPER | c.1793A>G p.Y598C | Missense Mutation (SNP) | VAF 141/422 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs1002066204; called by muse, mutect2
- BMT2 | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV51778386; called by muse, mutect2, varscan2
- BNC2 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 91/371 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs756459154, COSV101033320, COSV66149708; called by muse, mutect2, varscan2
- BOD1L1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 102/379 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50015843, COSV99240474; called by muse, mutect2, varscan2
- BRAF | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 116/492 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV56144127; called by muse, mutect2, varscan2
- BRCA2 | c.3775A>C p.S1259R | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as rs587782071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.8018A>C p.K2673T | Missense Mutation (SNP) | VAF 120/407 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66464740; called by muse, mutect2, varscan2
- BRCC3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV57462323; called by muse, mutect2, varscan2
- BRINP2 | c.2104C>A p.L702I | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV64175866, COSV64180538; called by muse, mutect2, varscan2
- BRINP3 | c.688C>A p.L230M | Missense Mutation (SNP) | VAF 63/710 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66519186; called by muse, mutect2
- BRMS1 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60820270; called by muse, mutect2, varscan2
- BRPF1 | c.1983+7G>A | Splice Region (SNP) | VAF 78/230 reads (34%) | catalogued as rs751452778; called by muse, mutect2, varscan2
- BRWD3 | c.5237G>A p.R1746Q | Missense Mutation (SNP) | VAF 127/414 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.953); catalogued as rs918551619, COSV100956683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 80/328 reads (24%) | catalogued as COSV64748961, COSV64754484; called by muse, mutect2, varscan2
- BSPH1 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60413196; called by muse, mutect2, varscan2
- BTBD7 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 114/449 reads (25%) | catalogued as rs1017916547, COSV100597990, COSV58285585; called by muse, mutect2, varscan2
- BTBD8 | c.3608C>T p.S1203L (on ENST00000636805 / NM_001376131.1; = p.S690L on NM_015237.4) | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1040167764; called by muse, mutect2
- BTK | c.1645G>T p.D549Y | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58123080; called by muse, mutect2, varscan2
- BTK | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 156/400 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100437735; called by muse, mutect2, varscan2
- BTNL3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs778473610, COSV61564442; called by muse, mutect2, varscan2
- BTNL9 | c.560G>T p.R187I | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV59794831, COSV59795131; called by muse, mutect2, varscan2
- BTRC | c.1537C>T p.R513* (on ENST00000370187 / NM_033637.4; = p.R477* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 116/398 reads (29%) | catalogued as rs568788208, COSV64579105; called by muse, mutect2, varscan2
- BUB1B | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 105/376 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755579898, COSV55011588; called by muse, mutect2, varscan2
- BZW1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 174/587 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV63349698; called by muse, mutect2, varscan2
- C14orf39 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 62/234 reads (26%) | catalogued as COSV100408121; called by muse, mutect2, varscan2
- C16orf89 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs1366296763, COSV60125129; called by muse, varscan2
- C17orf99 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs948785372; called by muse, varscan2
- C18orf54 | c.626G>T p.R209I | Missense Mutation (SNP) | VAF 88/361 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV55617296; called by muse, mutect2, varscan2
- C1QL4 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs750966716, COSV57743425; called by muse, mutect2, varscan2
- C1QTNF12 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs369520877; called by muse, mutect2, varscan2
- C1S | c.421G>T p.V141F | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs782567111; called by mutect2, varscan2
- C1orf43 | c.578G>A p.R193Q (on ENST00000368521 / NM_001297718.2; = p.R159Q on NM_015449.4) | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1016886052, COSV62965968; called by muse, mutect2, varscan2
- C1orf87 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 111/406 reads (27%) | catalogued as rs147997086, COSV64596556; called by muse, mutect2, varscan2
- C22orf15 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.088); catalogued as rs1202464682; called by muse, mutect2, varscan2
- C2CD3 | c.1070C>A p.S357Y | Missense Mutation (SNP) | VAF 33/384 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as COSV58089406; called by muse, mutect2
- C2CD5 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 57/233 reads (24%) | catalogued as COSV61723130, COSV61724471; called by muse, mutect2, varscan2
- C2CD5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 188/620 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61722731; called by muse, mutect2, varscan2
- C2CD5 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 150/489 reads (31%) | catalogued as COSV61727203; called by muse, mutect2, varscan2
- C3orf20 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 107/317 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs768861528, COSV53782331, COSV99513234; called by muse, mutect2, varscan2
- C3orf38 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 84/517 reads (16%) | catalogued as rs1285309231, COSV59627517; called by muse, mutect2, varscan2
- C4BPA | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 44/662 reads (7%) | catalogued as COSV65536576; called by muse, mutect2
- C4orf46 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 199/644 reads (31%) | catalogued as rs749789362, COSV57014249; called by mutect2, varscan2
- C7 | c.1710C>A p.F570L | Missense Mutation (SNP) | VAF 121/421 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV100496155; called by muse, mutect2, varscan2
- C7orf31 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs531648664, COSV52216035; called by muse, mutect2, varscan2
- C9orf43 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55913556; called by muse, mutect2
- C9orf78 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 43/569 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs779411568; called by muse, mutect2
- CAB39L | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs780505672, COSV61713671; called by muse, varscan2
- CACNA1D | c.3622G>A p.E1208K (on ENST00000350061 / NM_001128840.3; = p.E1228K on NM_000720.4) | Missense Mutation (SNP) | VAF 52/476 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55445291; called by muse, mutect2, varscan2
- CACNA1F | c.1794C>A p.C598* | Nonsense Mutation (SNP) | VAF 24/294 reads (8%) | catalogued as CM158286, COSV59903681; called by muse, mutect2
- CACNA1S | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs756920981; called by muse, varscan2
- CACNB2 | c.1075G>A p.E359K (on ENST00000324631 / NM_201596.3; = p.E304K on NM_000724.4) | Missense Mutation (SNP) | VAF 91/288 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV56633541; called by muse, varscan2
- CACNB4 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 113/363 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs767538753, COSV52399686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG6 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV53165592; called by muse, mutect2, varscan2
- CALCRL | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV66475990, COSV66476528; called by muse, mutect2, varscan2
- CALHM2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as rs777338270; called by muse, varscan2
- CALR3 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 112/389 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs550089146, COSV54168698; called by muse, mutect2, varscan2
- CAMK2G | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs761674491, COSV59485330; called by muse, varscan2
- CAMKK1 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279529960; called by muse, mutect2, varscan2
- CAMSAP2 | c.3964C>T p.R1322C (on ENST00000236925 / NM_001297707.2; = p.R1311C on NM_203459.3) | Missense Mutation (SNP) | VAF 131/712 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs140682641; called by muse, mutect2, varscan2
- CAPN2 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 135/681 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1010016325, COSV54337515; called by muse, mutect2, varscan2
- CAPN5 | c.1297G>A p.E433K (on ENST00000456580; = p.E393K on NM_004055.5) | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs369845664; called by muse, mutect2, varscan2
- CAPN9 | c.809G>T p.R270I | Missense Mutation (SNP) | VAF 95/413 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV55232544; called by muse, mutect2, varscan2
- CASD1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV51974004; called by muse, mutect2
- CASK | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 105/352 reads (30%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs868537608, COSV59374892; called by muse, mutect2, varscan2
- CASKIN2 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs200961448; called by muse, mutect2, varscan2
- CASP8 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51846504, COSV99965286, COSV99965729; called by muse, mutect2, varscan2
- CATSPERB | c.1472G>T p.R491I | Missense Mutation (SNP) | VAF 17/353 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as COSV56424364; called by muse, mutect2
- CBLN2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99504129; called by mutect2, varscan2
- CBWD2 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52073508; called by mutect2, varscan2
- CBX3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 154/942 reads (16%) | catalogued as COSV61761318; called by muse, varscan2
- CCAR1 | c.3289T>G p.L1097V | Missense Mutation (SNP) | VAF 97/350 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.987); catalogued as rs1040189895, COSV99771223; called by muse, mutect2, varscan2
- CCDC148 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 144/523 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs140798767; called by muse, mutect2, varscan2
- CCDC149 | c.1130C>T p.S377L (on ENST00000635206 / NM_001330643.2; = p.S366L on NM_173463.5) | Missense Mutation (SNP) | VAF 131/371 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as rs373188183; called by muse, mutect2, varscan2
- CCDC168 | c.16274G>T p.R5425I | Missense Mutation (SNP) | VAF 109/394 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV104400445; called by muse, mutect2, varscan2
- CCDC168 | c.14681G>T p.R4894I | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV104400374; called by muse, mutect2
- CCDC174 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 104/446 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs201187132; called by muse, varscan2
- CCDC181 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 44/439 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376964448; called by muse, mutect2, varscan2
- CCDC196 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 47/461 reads (10%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.017); catalogued as rs866116538; called by muse, mutect2, varscan2
- CCDC39 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 152/493 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1458123630, COSV56483732; called by muse, mutect2, varscan2
- CCDC6 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 127/470 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.338); catalogued as COSV54055823; called by muse, mutect2, varscan2
- CCDC88C | c.4703C>T p.S1568L | Missense Mutation (SNP) | VAF 194/524 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as rs752668368, COSV57796258; called by muse, mutect2, varscan2
- CCKBR | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs1382735537; called by muse, mutect2, varscan2
- CCKBR | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs773790618, COSV58106563; called by muse, mutect2, varscan2
- CCKBR | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV58100786; called by muse, mutect2
- CCKBR | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs865919804, COSV58100422; called by muse, mutect2, varscan2
- CCN2 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 132/454 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63466512; called by muse, mutect2, varscan2
- CCNB2 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs531597901, COSV55596186; called by muse, mutect2, varscan2
- CCNB3 | c.1738G>T p.V580L | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as COSV99328254; called by muse, mutect2
- CCNE1 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs774836905; called by muse, mutect2, varscan2
- CCNF | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV99564149; called by muse, mutect2, varscan2
- CCNI | c.32G>T p.R11I | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1248319573; called by muse, mutect2
- CCPG1 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 129/402 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs753064740; called by muse, mutect2, varscan2
- CCR7 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1442842565, COSV55849574; called by muse, mutect2, varscan2
- CCSER1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs745548077, COSV100390706, COSV61437396; called by muse, mutect2, varscan2
- CCSER2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs200068948, COSV56512306; called by muse, mutect2, varscan2
- CD101 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 155/525 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200228819; called by muse, mutect2, varscan2
- CD180 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 128/408 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1038384169, COSV56516797, COSV56517903; called by muse, mutect2, varscan2
- CD22 | c.2512G>T p.E838* | Nonsense Mutation (SNP) | VAF 29/337 reads (9%) | catalogued as COSV50050498, COSV99323860; called by muse, mutect2
- CD69 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 119/428 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as rs142870511; called by muse, mutect2, varscan2
- CDC26 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 94/397 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs764264213, COSV65252464, COSV65252631; called by muse, mutect2, varscan2
- CDC37 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs767381772; called by muse, mutect2, varscan2
- CDC40 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 97/334 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1244226490, COSV57008311; called by muse, mutect2, varscan2
- CDCA5 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1340393208; called by muse, mutect2, varscan2
- CDH2 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 111/346 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1371255423, COSV99296158; called by muse, mutect2, varscan2
- CDH2 | c.745A>G p.N249D | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.069); catalogued as COSV52297179; called by muse, mutect2, varscan2
- CDH23 | c.1450-1G>A p.X484_splice | Splice Site (SNP) | VAF 52/207 reads (25%) | catalogued as rs747981278; called by muse, mutect2, varscan2
- CDH5 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1342694698; called by muse, mutect2, varscan2
- CDH7 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as COSV59886164; called by muse, mutect2
- CDK12 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 130/520 reads (25%) | catalogued as COSV101420628; called by muse, mutect2, varscan2
- CDK13 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1188926859, COSV51696530; called by muse, mutect2, varscan2
- CDK19 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 123/482 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.34); catalogued as rs953895657; called by muse, mutect2, varscan2
- CDK4 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs373619077, COSV56984381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs141387242; called by muse, mutect2, varscan2
- CDK7 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 127/533 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56511769, COSV56515140; called by muse, mutect2, varscan2
- CDKL3 | c.1757G>T p.R586I | Missense Mutation (SNP) | VAF 113/336 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV54740468; called by muse, mutect2, varscan2
- CDKL5 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 133/395 reads (34%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV66110977; called by muse, mutect2, varscan2
- CDKL5 | c.2369C>A p.S790Y | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as COSV66114309; called by muse, mutect2, varscan2
- CDNF | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV101012390; called by muse, mutect2, varscan2
- CEACAM18 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV101140335; called by muse, varscan2
- CEL | c.642C>A p.F214L (on ENST00000673714; = p.F211L on NM_001807.6) | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV60827156; called by muse, mutect2, varscan2
- CENPE | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs866905901, COSV54378711; called by muse, varscan2
- CENPF | c.86A>C p.K29T | Missense Mutation (SNP) | VAF 166/760 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65273776; called by muse, mutect2, varscan2
- CENPF | c.5911T>C p.S1971P | Missense Mutation (SNP) | VAF 95/439 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV65274736; called by mutect2, varscan2
- CENPS | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 144/467 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs759332241, COSV58364265; called by muse, mutect2, varscan2
- CEP126 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 134/529 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432108672, COSV54822807; called by muse, mutect2, varscan2
- CEP126 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 75/212 reads (35%) | catalogued as COSV54821526; called by muse, mutect2, varscan2
- CEP135 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 28/305 reads (9%) | catalogued as COSV57260784, COSV99954689; called by muse, mutect2
- CEP162 | c.1920C>A p.F640L | Missense Mutation (SNP) | VAF 96/314 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.12); catalogued as COSV100003406; called by muse, mutect2, varscan2
- CEP170 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 86/465 reads (18%) | catalogued as COSV60508726; called by muse, varscan2
- CEP290 | c.3037G>T p.E1013* | Nonsense Mutation (SNP) | VAF 85/288 reads (30%) | catalogued as CM072942, COSV58350039; called by mutect2, varscan2
- CEP290 | c.2067G>T p.K689N | Missense Mutation (SNP) | VAF 35/394 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV100470277, COSV58351383; called by muse, mutect2
- CEP41 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1210916591; called by muse, mutect2, varscan2
- CEP44 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs368964236; called by muse, mutect2, varscan2
- CERS3 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 116/348 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52565563; called by muse, mutect2, varscan2
- CERS4 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1407588961; called by muse, mutect2, varscan2
- CERS5 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV58190080; called by muse, mutect2
- CES3 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 135/235 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs376329904, COSV57593280; called by muse, mutect2, varscan2
- CETN2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 55/268 reads (21%) | catalogued as COSV100938618; called by muse, mutect2, varscan2
- CETN3 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 96/714 reads (13%) | catalogued as rs1328760562, COSV51617259; called by muse, mutect2, varscan2
- CFAP100 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.761); catalogued as rs765883697, COSV61504382; called by muse, mutect2, varscan2
- CFAP43 | c.3617G>T p.R1206I | Missense Mutation (SNP) | VAF 115/447 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV100829466; called by muse, mutect2, varscan2
- CFAP45 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 106/460 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100928630; called by muse, mutect2, varscan2
- CFAP47 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 49/599 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as rs1338138613; called by muse, mutect2
- CFAP47 | c.5831G>A p.R1944H | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1226317867, COSV66195251; called by muse, varscan2
- CFAP57 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 107/354 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749165112; called by muse, mutect2, varscan2
- CFAP69 | c.1245G>T p.Q415H | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100290554; called by muse, mutect2
- CFAP74 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376185684; called by muse, mutect2
- CFAP91 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142545565; called by muse, mutect2, varscan2
- CFHR1 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57626879; called by muse, mutect2, varscan2
- CHAC1 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 34/638 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV71436246; called by muse, mutect2
- CHD2 | c.4711G>A p.D1571N | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.2); catalogued as rs780123418; called by muse, mutect2, varscan2
- CHD4 | c.5318G>A p.R1773Q (on ENST00000357008 / NM_001363606.2; = p.R1784Q on NM_001273.5) | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1438981469, COSV58898333; called by muse, mutect2, varscan2
- CHD5 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 112/363 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as rs777905560; called by muse, mutect2, varscan2
- CHD6 | c.973T>G p.F325V | Missense Mutation (SNP) | VAF 34/389 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58555363; called by muse, mutect2
- CHD7 | c.825C>A p.F275L | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV71114560; called by muse, mutect2, varscan2
- CHD8 | c.5680C>T p.R1894W (on ENST00000646647 / NM_001170629.2; = p.R1615W on NM_020920.4) | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs974840941; called by muse, mutect2, varscan2
- CHD8 | c.1444C>T p.R482* (on ENST00000646647 / NM_001170629.2; = p.R203* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 116/315 reads (37%) | catalogued as COSV67870230; called by muse, mutect2, varscan2
- CHKB | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 114/298 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs200919604, COSV56414909; ClinVar: uncertain significance; called by muse, varscan2
- CHM | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs773682340; called by muse, mutect2
- CHRDL1 | c.1005C>A p.F335L (on ENST00000372045; = p.F341L on NM_145234.4) | Missense Mutation (SNP) | VAF 117/377 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54326274; called by muse, mutect2, varscan2
- CHRM4 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as rs780553103, COSV100708753; called by muse, mutect2, varscan2
- CHRNA9 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 190/492 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs139982841, CM1414136; called by muse, mutect2
- CHRNB3 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 29/311 reads (9%) | catalogued as rs75170626, COSV51497255; called by muse, mutect2
- CHSY1 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 143/470 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs776069033, COSV54252183; called by muse, mutect2, varscan2
- CHTF18 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50100722; called by muse, mutect2, varscan2
- CIP2A | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 119/366 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767069025, COSV55418459; called by muse, mutect2, varscan2
- CISD1 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); catalogued as COSV61704067; called by muse, mutect2, varscan2
- CISD3 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 131/371 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1353251564; called by muse, mutect2, varscan2
- CIT | c.4267G>A p.E1423K | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.207); catalogued as rs150217898; called by muse, mutect2, varscan2
- CKAP2 | c.305C>A p.P102H (on ENST00000378037 / NM_001098525.2; = p.P101H on NM_018204.5) | Missense Mutation (SNP) | VAF 101/343 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51620833; called by muse, mutect2, varscan2
- CKM | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as rs200170574, COSV55532790; called by muse, mutect2, varscan2
- CLASP1 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs371571878; called by muse, mutect2, varscan2
- CLASP2 | c.3938C>A p.S1313Y (on ENST00000359576; = p.S1312Y on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/366 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV56281402; called by muse, mutect2, varscan2
- CLASP2 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs1362042788, COSV104407415; called by muse, mutect2
- CLCA4 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 141/501 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.743); catalogued as rs369186095; called by muse, mutect2, varscan2
- CLCN1 | c.1890G>T p.Q630H | Missense Mutation (SNP) | VAF 104/368 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.092); catalogued as rs1302946040; called by muse, mutect2, varscan2
- CLEC5A | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV69397018; called by muse, mutect2, varscan2
- CLINT1 | c.222G>T p.K74N | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as rs1199604308, COSV51621951; called by muse, mutect2
- CLMP | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 26/128 reads (20%) | catalogued as rs766246908; called by muse, mutect2, varscan2
- CLTCL1 | c.4771C>A p.L1591I (on ENST00000427926 / NM_007098.4; = p.L1534I on NM_001835.4) | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV53206326; called by muse, mutect2
- CMKLR1 | c.995C>A p.S332Y (on ENST00000312143 / NM_001142344.2; = p.S330Y on NM_004072.3) | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56436276; called by muse, mutect2, varscan2
- CNKSR1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 93/332 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.488); catalogued as rs754881477, COSV100836664; called by muse, mutect2, varscan2
- CNKSR3 | c.1578G>T p.K526N | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs1209760782; called by muse, mutect2, varscan2
- CNOT1 | c.3565C>T p.R1189C | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV55315943; called by muse, mutect2
- CNTNAP2 | c.3262C>T p.R1088* | Nonsense Mutation (SNP) | VAF 60/216 reads (28%) | catalogued as rs766777011, COSV62164786; called by muse, mutect2
- CNTNAP5 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 106/449 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757108906, COSV70486167; called by muse, mutect2, varscan2
- CNTRL | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 73/260 reads (28%) | catalogued as rs1229040329; called by muse, mutect2, varscan2
- COL11A1 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 29/121 reads (24%) | catalogued as COSV100614907, COSV62176520, COSV62184186; called by mutect2, varscan2
- COL11A1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.905); catalogued as rs1341498364, COSV62186825; called by muse, mutect2, varscan2
- COL14A1 | c.3358C>T p.R1120* | Nonsense Mutation (SNP) | VAF 78/290 reads (27%) | catalogued as rs779378321, COSV52852069, COSV52861310; called by muse, varscan2
- COL15A1 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 63/209 reads (30%) | catalogued as COSV100897626; called by mutect2, varscan2
- COL1A1 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 28/295 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs376564562; ClinVar: uncertain significance; called by muse, mutect2
- COL20A1 | c.2079C>A p.I693= | Splice Region (SNP) | VAF 24/86 reads (28%) | catalogued as COSV100491630; called by muse, mutect2, varscan2
- COL21A1 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770639332, COSV55161169, COSV55161225; called by muse, varscan2
- COL21A1 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 110/322 reads (34%) | catalogued as COSV55158041; called by muse, mutect2, varscan2
- COL24A1 | c.4835C>T p.S1612L | Missense Mutation (SNP) | VAF 94/361 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs773684520, COSV65314341; called by muse, mutect2, varscan2
- COL24A1 | c.3982C>A p.L1328I | Missense Mutation (SNP) | VAF 80/281 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV65304646, COSV65314258; called by muse, mutect2, varscan2
- COL27A1 | c.3040C>T p.R1014C | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752193524; called by muse, mutect2, varscan2
- COL2A1 | c.4204G>A p.E1402K | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs759583931, COSV61528864; called by muse, mutect2, varscan2
- COL6A1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.393); catalogued as rs200389937; called by muse, mutect2, varscan2
- COL6A3 | c.3145G>T p.E1049* | Nonsense Mutation (SNP) | VAF 24/307 reads (8%) | catalogued as COSV99800708; called by muse, mutect2
- COL6A5 | c.7504G>A p.D2502N (on ENST00000312481; = p.D2498N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/369 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs752185068, COSV99593495; called by muse, mutect2, varscan2
- COL9A1 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 87/330 reads (26%) | catalogued as COSV57879746; called by muse, mutect2, varscan2
- COLGALT2 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 49/232 reads (21%) | catalogued as rs373361853, COSV62298805; called by muse, mutect2, varscan2
- COPB1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 93/344 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369909236; called by muse, varscan2
- COQ8A | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143816043; called by muse, mutect2, varscan2
- CP | c.1918G>T p.D640Y | Missense Mutation (SNP) | VAF 113/411 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CD067161, CP025132, COSV52832203; called by muse, mutect2, varscan2
- CPA1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148329227, COSV50575831; called by muse, mutect2, varscan2
- CPB1 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 114/383 reads (30%) | catalogued as rs772369161; called by muse, varscan2
- CPD | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 105/318 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs749464593, COSV99852783; called by muse, mutect2, varscan2
- CPSF4 | c.306C>T p.F102= | Splice Region (SNP) | VAF 25/100 reads (25%) | catalogued as rs767880639; called by muse, mutect2, varscan2
- CRACDL | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 151/589 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV67406441; called by muse, mutect2, varscan2
- CRB2 | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs542637649; called by muse, mutect2, varscan2
- CREBBP | c.2264G>T p.S755I | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.618); catalogued as COSV104387923; called by muse, mutect2, varscan2
- CRNN | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 96/376 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs184532873; called by muse, mutect2
- CRYBG2 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1203773831, COSV57485573; called by muse, mutect2, varscan2
- CRYBG3 | c.3117G>T p.K1039N | Missense Mutation (SNP) | VAF 86/296 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs545501003; called by mutect2, varscan2
- CSMD1 | c.4317C>A p.F1439L (on ENST00000520002; = p.F1438L on NM_033225.6) | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as COSV59298436; called by muse, mutect2, varscan2
- CSMD2 | c.9207C>A p.F3069L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV53913629; called by muse, mutect2, varscan2
- CSMD2 | c.8389C>T p.R2797W | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); catalogued as rs746116665, COSV53890915; called by muse, mutect2, varscan2
- CSMD2 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs1391408280, COSV53878811; called by muse, mutect2
- CSMD3 | c.2719C>A p.L907I (on ENST00000297405 / NM_001363185.1; = p.L803I on NM_052900.3) | Missense Mutation (SNP) | VAF 43/461 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52320138; called by muse, mutect2
- CSMD3 | c.2032G>A p.D678N (on ENST00000297405 / NM_001363185.1; = p.D574N on NM_052900.3) | Missense Mutation (SNP) | VAF 135/484 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.418); catalogued as rs142207091, COSV99838134; called by muse, mutect2, varscan2
- CSNK1D | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs774858511, COSV53925579; called by muse, mutect2, varscan2
- CSNK2A1 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 118/338 reads (35%) | catalogued as COSV104372006; called by muse, mutect2, varscan2
- CST11 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV100983564; called by muse, mutect2, varscan2
- CT83 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 23/699 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs184008196, COSV100902566; called by muse, mutect2
- CTAGE1 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 90/279 reads (32%) | catalogued as COSV66943266; called by muse, mutect2, varscan2
- CTDP1 | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777623040, COSV50001698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.2258C>A p.S753Y | Missense Mutation (SNP) | VAF 124/437 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58153166; called by muse, mutect2, varscan2
- CTNND1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 117/338 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1406000983, COSV62383129, COSV62384953; called by muse, mutect2, varscan2
- CTNS | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 139/433 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as rs555311279, COSV50439978; called by muse, mutect2, varscan2
- CTSC | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 111/385 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1324949386; called by muse, mutect2, varscan2
- CUBN | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64701968; called by muse, mutect2, varscan2
- CUL2 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs749443608, COSV66078880; called by muse, mutect2, varscan2
- CWC22 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.921); catalogued as rs200967500; called by muse, mutect2, varscan2
- CXCL17 | c.192C>A p.F64L | Missense Mutation (SNP) | VAF 21/594 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1273403828; called by muse, mutect2
- CYB561D1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1234971236, COSV100149777; called by muse, mutect2, varscan2
- CYB5D1 | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV99641878; called by muse, mutect2, varscan2
- CYP17A1 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV64004932; called by muse, mutect2, varscan2
- CYP26A1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV56416884; called by muse, mutect2
- CYP2A13 | c.1228G>T p.D410Y | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as rs780068442; called by muse, mutect2, varscan2
- CYP2A6 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs773401076; called by muse, mutect2, varscan2
- CYP2C18 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 108/377 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV99608712; called by muse, mutect2, varscan2
- CYP2J2 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 142/436 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774331140, COSV64607342; called by muse, mutect2, varscan2
- CYP2J2 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 55/158 reads (35%) | catalogued as rs899892667, COSV64605512; called by mutect2, varscan2
- CYP2U1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV60549626; called by muse, mutect2, varscan2
- CYP3A4 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60504759; called by muse, mutect2, varscan2
- CYP4X1 | c.1512G>T p.K504N | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV64150677; called by muse, varscan2
- CYP8B1 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs762230983, COSV60226483; called by muse, mutect2, varscan2
- CYRIA | c.855A>C p.K285N | Missense Mutation (SNP) | VAF 84/309 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV62864409, COSV62865839, COSV62867483; called by muse, mutect2, varscan2
- DAB2IP | c.493C>A p.L165I (on ENST00000408936; = p.L137I on NM_032552.3) | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52256933; called by muse, mutect2, varscan2
- DACT1 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs776160196, COSV60020789; called by muse, mutect2, varscan2
- DACT1 | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60023876; called by muse, mutect2, varscan2
- DAO | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201583577; called by muse, mutect2, varscan2
- DAPK1 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 141/416 reads (34%) | catalogued as COSV100800726; called by muse, mutect2, varscan2
- DBF4B | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as rs774436262, COSV59258932, COSV59261867; called by muse, varscan2
- DBH | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368994366; called by muse, mutect2, varscan2
- DCAF10 | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54287205, COSV99647540; called by muse, mutect2, varscan2
- DCAF13 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1425272025, COSV52570614; called by muse, mutect2, varscan2
- DCAF6 | c.2242C>T p.R748W (on ENST00000312263 / NM_001349778.1; = p.R768W on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 180/749 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745724831; called by muse, varscan2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 138/463 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- DCLK2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 106/336 reads (32%) | catalogued as COSV56200287; called by muse, mutect2, varscan2
- DCLRE1A | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 149/456 reads (33%) | catalogued as rs1212761218, COSV100800363; called by muse, mutect2, varscan2
- DCSTAMP | c.1347C>A p.F449L | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV52575994; called by muse, mutect2, varscan2
- DCTN3 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as rs765619518; called by muse, mutect2, varscan2
- DDX10 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 39/235 reads (17%) | catalogued as COSV100489936; called by muse, mutect2, varscan2
- DDX17 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 122/408 reads (30%) | catalogued as COSV53247135, COSV53249825; called by muse, mutect2, varscan2
- DDX23 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV56397324; called by muse, varscan2
- DDX43 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV64836662; called by muse, mutect2, varscan2
- DDX53 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 131/406 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60070174; called by muse, mutect2, varscan2
- DEDD | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs754848698, COSV63502143; called by muse, mutect2, varscan2
- DENND4C | c.4111C>T p.R1371C (on ENST00000434457 / NM_001330640.2; = p.R1322C on NM_017925.7) | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs981244698; called by muse, mutect2
- DEPDC1B | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 61/223 reads (27%) | catalogued as rs575323127, COSV54009042; called by muse, mutect2, varscan2
- DEPDC1B | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs201451342, COSV54013086; called by muse, mutect2, varscan2
- DERL2 | c.238C>A p.R80S | Missense Mutation (SNP) | VAF 92/393 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50148031; called by mutect2, varscan2
- DGAT2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.957); catalogued as rs545718921; called by muse, mutect2, varscan2
- DGKD | c.3301G>A p.E1101K (on ENST00000264057 / NM_152879.3; = p.E1057K on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as rs991285626; called by muse, mutect2, varscan2
- DGKI | c.2382G>T p.E794D | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1377978333; called by muse, mutect2, varscan2
- DHFR | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1456478807, COSV71485479; called by muse, mutect2, varscan2
- DHRS7C | c.449C>T p.A150V (on ENST00000330255 / NM_001220493.2; = p.A149V on NM_001105571.3) | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs773513074; called by muse, mutect2, varscan2
- DHRSX | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 22/341 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754962533; called by muse, mutect2
- DHTKD1 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 89/444 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs371485560; called by muse, mutect2, varscan2
- DHX29 | c.2719C>A p.L907I | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); catalogued as rs964030340; called by muse, mutect2
- DHX40 | c.1913G>T p.R638I | Missense Mutation (SNP) | VAF 141/445 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99232976; called by muse, mutect2, varscan2
- DIAPH3 | c.2698T>G p.F900V (on ENST00000400324 / NM_001042517.2; = p.F637V on NM_030932.3) | Missense Mutation (SNP) | VAF 131/443 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757481645; called by mutect2, varscan2
- DIPK2B | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs746307645; called by muse, mutect2, varscan2
- DIS3 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 191/670 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs763490458, COSV58328266; called by muse, mutect2, varscan2
- DIXDC1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1027236169, COSV100180031, COSV59460966; called by muse, mutect2, varscan2
- DLC1 | c.2338G>A p.D780N (on ENST00000276297 / NM_001348081.2; = p.D343N on NM_006094.5) | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV52300754; called by muse, varscan2
- DLGAP5 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 103/419 reads (25%) | catalogued as rs774608538, COSV55962038; called by muse, mutect2, varscan2
- DMRT3 | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as rs763720874; called by muse, mutect2, varscan2
- DMTN | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371569595, COSV56111740; called by muse, varscan2
- DMXL1 | c.6125G>A p.R2042H | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1339119066, COSV60705408; called by muse, mutect2, varscan2
- DMXL2 | c.278G>T p.R93I | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV99195926; called by muse, mutect2, varscan2
- DNAAF2 | c.2381C>T p.T794M | Missense Mutation (SNP) | VAF 121/469 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs185361306, COSV53566940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs938070698, COSV101325736; called by muse, mutect2, varscan2
- DNAH11 | c.4670G>A p.R1557Q | Missense Mutation (SNP) | VAF 140/461 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs1166407911, COSV100178473, COSV60966002; called by muse, mutect2, varscan2
- DNAH12 | c.3673C>T p.R1225* (on ENST00000351747; = p.R1248* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 85/274 reads (31%) | catalogued as rs981533821; called by muse, mutect2, varscan2
- DNAH14 | c.5344C>T p.R1782C (on ENST00000445597; = p.R2187C on NM_001367479.1) | Missense Mutation (SNP) | VAF 121/605 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs993935877, COSV59899326; called by muse, mutect2, varscan2
- DNAH17 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs768308901, COSV101102013, COSV67758449; called by muse, mutect2, varscan2
- DNAH2 | c.2510G>A p.R837H | Missense Mutation (SNP) | VAF 102/274 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs779653586, COSV101209097; called by muse, mutect2, varscan2
- DNAH3 | c.8904G>T p.E2968D | Missense Mutation (SNP) | VAF 97/292 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104372710; called by muse, mutect2, varscan2
- DNAH3 | c.2563A>G p.T855A | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1429801892; called by muse, mutect2, varscan2
- DNAH3 | c.1946G>T p.R649I | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as rs188652923, COSV99770280; called by muse, mutect2
- DNAH6 | c.8677C>T p.R2893* | Nonsense Mutation (SNP) | VAF 127/401 reads (32%) | catalogued as rs552500475, COSV52850352; called by muse, mutect2, varscan2
- DNAH7 | c.6223C>A p.L2075I | Missense Mutation (SNP) | VAF 127/423 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.612); catalogued as rs1338784675, COSV56781678; called by muse, mutect2, varscan2
- DNAH7 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs780057760, COSV56758361; called by muse, mutect2, varscan2
- DNAH7 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 133/453 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs770564417; called by muse, mutect2, varscan2
- DNAH8 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as rs138901149; called by muse, mutect2, varscan2
- DNAI4 | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 54/189 reads (29%) | catalogued as rs758550177, COSV64022904; called by muse, varscan2
- DNAJA1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 114/399 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs141132012; called by muse, mutect2, varscan2
- DNAJB1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs765857048; called by muse, mutect2, varscan2
- DNAJC13 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 195/746 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs547360849, COSV53446557; called by muse, mutect2, varscan2
- DNAJC13 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 125/457 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs202069439; called by muse, mutect2, varscan2
- DNAJC13 | c.4101G>T p.E1367D | Missense Mutation (SNP) | VAF 44/494 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.095); catalogued as COSV53445499; called by muse, mutect2
- DNAJC27 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 58/486 reads (12%) | catalogued as rs1192797296, COSV53093961; called by muse, mutect2, varscan2
- DNAJC7 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1346751595, COSV57267880; called by muse, mutect2, varscan2
- DNAL1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 99/339 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as COSV60727344; called by muse, mutect2, varscan2
- DNM1 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV57855179; called by muse, mutect2, varscan2
- DNM3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 192/854 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766159947, COSV62458116; called by muse, mutect2, varscan2
- DNMBP | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs759738167, COSV60624289; called by muse, mutect2, varscan2
- DOCK10 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 114/393 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as rs775343177; called by muse, mutect2, varscan2
- DOCK11 | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 128/385 reads (33%) | catalogued as COSV99354069; called by muse, mutect2, varscan2
- DOCK2 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56975150; called by muse, mutect2, varscan2
- DOCK4 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 98/416 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.709); catalogued as rs868046387; called by muse, mutect2, varscan2
- DOCK6 | c.4738G>A p.D1580N | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762402181; called by muse, mutect2, varscan2
- DOCK7 | c.6298C>T p.R2100C (on ENST00000635253 / NM_001367561.1; = p.R2069C on NM_033407.3) | Missense Mutation (SNP) | VAF 49/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs763902201, COSV52013093; called by muse, mutect2, varscan2
- DOCK8 | c.6097C>T p.R2033C | Missense Mutation (SNP) | VAF 106/375 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs751058288, COSV66619972; called by muse, mutect2, varscan2
- DOP1A | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 87/442 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1468093035; called by muse, mutect2, varscan2
- DPPA3 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV61502790; called by muse, mutect2, varscan2
- DRC7 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs373094122; called by muse, mutect2, varscan2
- DSCC1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs144655317; called by muse, mutect2, varscan2
- DSEL | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 133/396 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100025957, COSV59494476; called by muse, varscan2
- DSG1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767678194, COSV57133741; called by muse, mutect2, varscan2
- DSG3 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 76/263 reads (29%) | catalogued as rs1472943015, COSV57125252, COSV99934677; called by muse, mutect2, varscan2
- DST | c.2489G>A p.R830Q (on ENST00000361203 / NM_001374722.1; = p.R504Q on NM_001723.6) | Missense Mutation (SNP) | VAF 146/492 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762435098; called by muse, mutect2, varscan2
- DTL | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 142/527 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs778583842; called by muse, mutect2, varscan2
- DUSP11 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 26/462 reads (6%) | catalogued as COSV55596579; called by muse, mutect2
- DUSP9 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as rs138533897; called by muse, mutect2, varscan2
- DUT | c.646C>T p.R216* (on ENST00000331200 / NM_001025248.2; = p.R128* on NM_001948.4) | Nonsense Mutation (SNP) | VAF 150/524 reads (29%) | catalogued as rs989363911; called by muse, mutect2, varscan2
- DYNC1H1 | c.12076G>A p.D4026N | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs768636289, COSV64140358; called by muse, mutect2, varscan2
- DYNC2H1 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs561232842, COSV62086954; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYNC2H1 | c.6044G>A p.R2015Q | Missense Mutation (SNP) | VAF 112/423 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs775984088, COSV62091815; called by muse, mutect2, varscan2
- DYNC2I1 | c.1815G>T p.E605D | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751206395; called by muse, mutect2, varscan2
- DYNLT3 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 126/481 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV66078739; called by mutect2, varscan2
- DYRK1A | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs556482236, COSV100117324; called by muse, mutect2, varscan2
- DYSF | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 114/356 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as rs886043461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYTN | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs369410820; called by muse, mutect2, varscan2
- E4F1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs920295834; called by muse, mutect2
- EBF2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68776583, COSV68780548; called by muse, varscan2
- ECE1 | c.1620C>A p.F540L | Missense Mutation (SNP) | VAF 108/360 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV99941319; called by muse, mutect2
- ECE2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs768830091; called by muse, mutect2, varscan2
- ECH1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.271); catalogued as rs1403167483; called by muse, mutect2, varscan2
- ECT2 | c.1784G>A p.R595Q (on ENST00000392692 / NM_001349098.2; = p.R564Q on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/826 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1253871843; called by muse, mutect2
- ECT2L | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs754540928, COSV62882962; called by muse, mutect2, varscan2
- EDRF1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 142/481 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.172); catalogued as COSV61766493; called by muse, mutect2, varscan2
- EEA1 | c.999G>T p.K333N | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59287992; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs748024573, COSV66964361; called by muse, mutect2, varscan2
- EEF2K | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs779040918; called by muse, mutect2, varscan2
- EFCAB13 | c.2792C>T p.S931L | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.024); catalogued as rs369709542, COSV58946115; called by muse, mutect2, varscan2
- EFHC1 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 208/608 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs766799700; called by muse, mutect2, varscan2
- EFR3A | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1291653738, COSV54459529; called by muse, mutect2, varscan2
- EFR3B | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101241465; called by muse, varscan2
- EFS | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs905331434; called by muse, mutect2, varscan2
- EGF | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as rs147634717, COSV54486379; called by muse, mutect2, varscan2
- EGFLAM | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs745930197, COSV59310512; called by muse, varscan2
- EGR2 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54347773; called by muse, mutect2, varscan2
- EHBP1 | c.3593C>T p.A1198V | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99859721; called by muse, mutect2, varscan2
- EHD4 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs958957223; called by muse, mutect2, varscan2
- EHF | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757126229, COSV57669499; called by muse, mutect2, varscan2
- EIF4E2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 182/531 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs925320031; called by muse, mutect2, varscan2
- EIF4EBP1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs751889248, COSV58774236; called by mutect2, varscan2
- ELOA | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 89/302 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV69311329; called by muse, mutect2, varscan2
- ELOA | c.1278C>A p.F426L | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV69309527, COSV69310785; called by muse, mutect2
- ELOA | c.1807C>A p.L603I | Missense Mutation (SNP) | VAF 100/328 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99072567; called by muse, mutect2, varscan2
- ELOVL1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 110/381 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201270403; called by muse, mutect2, varscan2
- EMC2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 151/502 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs1030080319; called by muse, mutect2, varscan2
- EMD | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as CD078077, COSV63962464; called by muse, mutect2, varscan2
- EML3 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 64/218 reads (29%) | catalogued as COSV53882422; called by muse, mutect2, varscan2
- ENDOD1 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773730577; called by muse, mutect2, varscan2
- ENKUR | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 86/289 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58633152; called by muse, mutect2, varscan2
- ENO1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 126/325 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs371689591; called by muse, mutect2, varscan2
- ENO2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 96/355 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs782101405; called by muse, mutect2, varscan2
- ENOX2 | c.1108C>T p.R370C (on ENST00000338144 / NM_001382520.1; = p.R341C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199818795, COSV57650385; called by muse, mutect2, varscan2
- ENPEP | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 69/227 reads (30%) | catalogued as rs143343563, COSV54448047; called by muse, mutect2, varscan2
- ENPEP | c.2672G>A p.R891Q | Missense Mutation (SNP) | VAF 127/446 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770598233, COSV54448376; called by muse, mutect2, varscan2
- EOLA2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as rs144047890; called by muse, mutect2, varscan2
- EP300 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54329321; called by muse, mutect2, varscan2
- EP400 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.654); catalogued as rs766432250, COSV57780225; called by muse, mutect2, varscan2
- EPB41 | c.2144G>A p.R715Q (on ENST00000343067 / NM_001166005.2; = p.R473Q on NM_004437.4) | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.752); catalogued as COSV58044896; called by muse, mutect2
- EPB41L5 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 142/439 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1414991675, COSV55354222; called by muse, mutect2, varscan2
- EPHA5 | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 126/427 reads (30%) | catalogued as COSV99899142; called by muse, mutect2, varscan2
- EPHA5 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 94/314 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs151302542; called by muse, mutect2, varscan2
- EPHB1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs764139128, COSV67657222, COSV67674992; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 182/708 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.05); catalogued as COSV51615868; called by muse, mutect2, varscan2
- EPRS1 | c.897G>T p.M299I | Missense Mutation (SNP) | VAF 89/482 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV65097640; called by muse, mutect2, varscan2
- EPS15 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs762929521; called by muse, mutect2, varscan2
- EPS15 | c.1816A>C p.S606R | Missense Mutation (SNP) | VAF 141/433 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV65540465; called by muse, mutect2, varscan2
- EPS8 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 113/416 reads (27%) | catalogued as rs1457535054, COSV55528972; called by muse, mutect2, varscan2
- ERAL1 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767871960; called by muse, mutect2, varscan2
- ERBB4 | c.3702G>T p.K1234N | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.122); catalogued as COSV100726245; called by muse, mutect2, varscan2
- ERBIN | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs776163114, COSV52313875, COSV99396521; called by muse, mutect2, varscan2
- ERGIC2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.558); catalogued as rs761613848; called by muse, mutect2, varscan2
- ERICH5 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 72/205 reads (35%) | catalogued as COSV59315405; called by muse, mutect2, varscan2
- ERMN | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 112/457 reads (25%) | catalogued as rs1469712056, COSV101263012, COSV68075619; called by muse, mutect2, varscan2
- ERO1A | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 91/323 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs774350848; called by muse, mutect2, varscan2
- ERO1A | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101193568; called by muse, mutect2
- ERV3-1 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 83/271 reads (31%) | catalogued as COSV104391654; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 15/374 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1049340035; called by muse, mutect2
- ESF1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 110/386 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs186231642, COSV52518687, COSV52523168; called by muse, mutect2, varscan2
- ESRP1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 32/494 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64412226; called by muse, mutect2
- ESYT1 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1373333554; called by muse, mutect2, varscan2
- ESYT3 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 93/309 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.342); catalogued as rs769328420, COSV56679687; called by muse, mutect2, varscan2
- ETV3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs1163203810, COSV58748797; called by muse, mutect2, varscan2
- EVC2 | c.2424G>T p.Q808H | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60398310; called by muse, varscan2
- EVL | c.303C>A p.F101L (on ENST00000402714 / NM_001330221.2; = p.F103L on NM_016337.3) | Missense Mutation (SNP) | VAF 117/411 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV101233107; called by muse, mutect2, varscan2
- EVL | c.992C>T p.S331L (on ENST00000402714 / NM_001330221.2; = p.S333L on NM_016337.3) | Missense Mutation (SNP) | VAF 110/260 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV67375968; called by muse, mutect2, varscan2
- EXOC2 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV57863551; called by muse, mutect2, varscan2
- EXOC7 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs769602819, COSV58743477; called by muse, mutect2, varscan2
- EXOC8 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 33/665 reads (5%) | catalogued as rs1314653490; called by muse, mutect2
- EXOC8 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 128/466 reads (27%) | catalogued as COSV50478059; called by muse, mutect2, varscan2
- EXTL2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 120/420 reads (29%) | catalogued as COSV64472964; called by muse, varscan2
- EYA1 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776314304, COSV100379413, COSV58158835; called by muse, mutect2, varscan2
- EYA2 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 109/382 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs769484018, COSV100427095; called by muse, mutect2, varscan2
- EYS | c.6957C>A p.F2319L | Missense Mutation (SNP) | VAF 124/419 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV65471997; called by muse, mutect2, varscan2
- EYS | c.5932G>A p.E1978K | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.346); catalogued as rs1023623666, COSV101005844; called by muse, mutect2
- EYS | c.4121G>A p.R1374Q | Missense Mutation (SNP) | VAF 118/439 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142187896; called by muse, mutect2, varscan2
- EYS | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 97/349 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765763663, COSV104424407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F5 | c.3409C>A p.Q1137K | Missense Mutation (SNP) | VAF 75/372 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as CM105383; called by muse, mutect2, varscan2
- F8 | c.4891G>A p.A1631T | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs781931217; called by muse, mutect2
- F8 | c.3407C>T p.S1136F | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.483); catalogued as COSV64273005, COSV64273639; called by muse, mutect2, varscan2
- F9 | c.89-1G>T p.X30_splice | Splice Site (SNP) | VAF 94/358 reads (26%) | catalogued as CS930794, CS941473, CS961561, CX962377; called by muse, mutect2
- F9 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 31/568 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99496280; called by muse, mutect2
- FAAH2 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs201590323; called by muse, mutect2, varscan2
- FAAH2 | c.1166G>T p.S389I | Missense Mutation (SNP) | VAF 98/348 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.492); catalogued as rs752160314; called by mutect2, varscan2
- FAM107B | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 81/289 reads (28%) | catalogued as rs778239622, COSV99473424, COSV99474364; called by muse, mutect2, varscan2
- FAM117B | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs750669692; called by muse, mutect2, varscan2
- FAM135A | c.1760C>A p.S587Y | Missense Mutation (SNP) | VAF 92/342 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99525747; called by muse, mutect2, varscan2
- FAM149B1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1480906623, COSV99654430; called by muse, mutect2, varscan2
- FAM166A | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140947216; called by muse, mutect2, varscan2
- FAM167A | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758382682, COSV52668399; called by muse, mutect2, varscan2
- FAM171B | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 133/369 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100488358; called by muse, mutect2, varscan2
- FAM186A | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 83/332 reads (25%) | catalogued as rs541010309, COSV59256231; called by muse, mutect2, varscan2
- FAM189A2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs764688447; called by muse, mutect2, varscan2
- FAM210B | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 134/473 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs17851557; called by muse, mutect2, varscan2
- FAM237A | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 118/326 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV101405598, COSV69304999; called by muse, mutect2, varscan2
- FAM47A | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1288586350; called by muse, mutect2, varscan2
- FAM47C | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.635); catalogued as rs1328446187; called by muse, mutect2, varscan2
- FAM83G | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs376887547; called by muse, mutect2, varscan2
- FANCB | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 111/254 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs1057515811, COSV60759570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANK1 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 155/459 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as COSV64137720; called by muse, mutect2, varscan2
- FAR2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as rs1475516172; called by muse, mutect2, varscan2
- FAT1 | c.2979G>T p.K993N | Missense Mutation (SNP) | VAF 118/401 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs1397804525, COSV104437747, COSV71673670; called by muse, mutect2, varscan2
- FAT2 | c.9487G>A p.D3163N | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.588); catalogued as rs141162743; called by muse, mutect2, varscan2
- FAT3 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 126/344 reads (37%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.806); catalogued as rs780987790, COSV53079281; called by muse, mutect2, varscan2
- FAT3 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 95/306 reads (31%) | catalogued as COSV53072200, COSV53124569, COSV99963822; called by muse, mutect2, varscan2
- FAT4 | c.4684G>T p.E1562* | Nonsense Mutation (SNP) | VAF 37/566 reads (7%) | catalogued as COSV67895770; called by muse, mutect2
- FBN1 | c.7883G>A p.S2628N | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57335253; called by muse, mutect2
- FBN1 | c.1035C>A p.C345* | Nonsense Mutation (SNP) | VAF 96/301 reads (32%) | catalogued as CM098623; called by muse, mutect2, varscan2
- FBN2 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 47/585 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs150735582, COSV52512855; ClinVar: uncertain significance; called by muse, mutect2
- FBN3 | c.5428C>T p.R1810W | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as rs902177398; called by muse, mutect2, varscan2
- FBXL3 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 147/503 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs560551710, COSV62918460; called by muse, mutect2, varscan2
- FBXO2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as rs369589187; called by muse, mutect2, varscan2
- FBXO38 | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 141/455 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV57030777; called by muse, mutect2, varscan2
- FBXO38 | c.3208C>T p.R1070* (on ENST00000340253 / NM_205836.3; = p.R995* on NM_030793.5) | Nonsense Mutation (SNP) | VAF 117/403 reads (29%) | catalogued as rs904657927, COSV57030854; called by muse, mutect2, varscan2
- FBXO4 | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 103/341 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV55852313; called by muse, mutect2, varscan2
- FBXW10 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1298042791; called by muse, mutect2, varscan2
- FBXW2 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs761775371; called by muse, mutect2, varscan2
- FBXW5 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs765886985; called by muse, mutect2, varscan2
- FBXW8 | c.242G>A p.R81Q (on ENST00000309909; = p.R119Q on NM_012174.1) | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1032919047; called by muse, mutect2, varscan2
- FCHSD2 | c.333C>A p.F111L | Missense Mutation (SNP) | VAF 115/453 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60812008; called by muse, mutect2, varscan2
- FDPS | c.353A>C p.N118T | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs907532468; called by muse, mutect2, varscan2
- FER1L6 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 106/404 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs191271444; called by muse, mutect2, varscan2
- FES | c.1784C>T p.T595M | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs141708381; called by muse, mutect2
- FES | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374728358; called by muse, varscan2
- FGA | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs763555716, COSV57393105; called by muse, mutect2, varscan2
- FGF19 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as COSV53736124; called by muse, mutect2, varscan2
- FGL2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 114/470 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as rs1459657752, COSV50381411; called by muse, mutect2, varscan2
- FH | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs200412958, COSV100845004, COSV100845021; called by muse, mutect2, varscan2
- FIG4 | c.1338C>A p.F446L | Missense Mutation (SNP) | VAF 87/563 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV57787589, COSV57788319; called by muse, mutect2, varscan2
- FILIP1 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.343); catalogued as rs868698674, COSV52728473; called by muse, mutect2, varscan2
- FLG | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as rs754135288; called by muse, mutect2, varscan2
- FLII | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs201233040, COSV57497649; called by muse, mutect2, varscan2
- FLRT3 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 80/258 reads (31%) | catalogued as COSV54002106; called by muse, mutect2, varscan2
- FLT4 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs752512978, COSV56105948; called by muse, mutect2, varscan2
- FMN2 | c.2188G>T p.E730* | Nonsense Mutation (SNP) | VAF 52/286 reads (18%) | catalogued as COSV60420787; called by muse, mutect2, varscan2
- FNDC3B | c.2378C>A p.S793Y | Missense Mutation (SNP) | VAF 73/295 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV61037832; called by muse, mutect2, varscan2
- FNDC7 | c.1997G>A p.G666D | Missense Mutation (SNP) | VAF 95/273 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763013847; called by muse, mutect2, varscan2
- FOXD1 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs1305057033; called by muse, mutect2, varscan2
- FOXD4L1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.374); catalogued as rs755139743, COSV52075704; called by muse, mutect2, varscan2
- FOXJ3 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 88/268 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as rs377432876; called by muse, mutect2, varscan2
- FPGT | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 126/356 reads (35%) | catalogued as COSV63834630; called by muse, mutect2, varscan2
- FRAS1 | c.6416C>A p.S2139Y | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53617529; called by muse, mutect2, varscan2
- FREM2 | c.3092C>A p.S1031Y | Missense Mutation (SNP) | VAF 108/342 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.205); catalogued as COSV54830140; called by mutect2, varscan2
- FRMD6 | c.532G>A p.E178K (on ENST00000344768 / NM_001267046.2; = p.E170K on NM_152330.4) | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as rs781384641, COSV100656397; called by muse, mutect2, varscan2
- FRMD7 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 140/440 reads (32%) | catalogued as COSV100048847, COSV100048949; called by muse, mutect2, varscan2
- FRMD7 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 94/393 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV53745261; called by muse, mutect2, varscan2
- FRMPD3 | c.2493C>A p.F831L | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV99347175; called by muse, mutect2, varscan2
- FRYL | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 110/338 reads (33%) | catalogued as COSV51962506; called by muse, mutect2, varscan2
- FSIP2 | c.1002G>T p.K334N | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as rs756690417; called by mutect2, varscan2
- FSIP2 | c.1825dup p.T609Nfs*17 | Frame Shift Ins (INS) | VAF 118/439 reads (27%) | catalogued as rs1334712288; called by mutect2, varscan2
- FSIP2 | c.13268C>A p.S4423Y | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs1423081278; called by muse, mutect2
- FSIP2 | c.15121C>A p.Q5041K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV58077376; called by muse, mutect2, varscan2
- FSIP2 | c.16948C>T p.R5650* | Nonsense Mutation (SNP) | VAF 93/278 reads (33%) | catalogued as rs746547008, COSV100555848, COSV58087277; called by muse, mutect2, varscan2
- FUBP1 | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs1286610435, COSV99629422; called by muse, mutect2, varscan2
- FUBP3 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 111/350 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV60513328; called by muse, mutect2, varscan2
- FUCA2 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 72/276 reads (26%) | catalogued as COSV99136078; called by muse, mutect2, varscan2
- FYCO1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 91/328 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs750946150; called by muse, mutect2, varscan2
- G6PC2 | c.83T>G p.F28C | Missense Mutation (SNP) | VAF 42/526 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56372690; called by muse, mutect2
- GABRA4 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 117/350 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV51924220; called by muse, mutect2, varscan2
- GABRG2 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.396); catalogued as rs1445637165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAD1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs1271415571, COSV60152097; called by muse, mutect2, varscan2
4,586 further variants in this file (3,314 protein-altering or splice-affecting, 1,058 silent, 214 other) are not listed here.
